TCGA case TCGA-AX-A06J — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b6819b52-6f01-4011-9bd3-a1a00397e0c9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,000 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 913 days (2.5 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 15.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 73 days; Days to treatment end: 87 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 107 days; Days to treatment end: 149 days; Number of cycles: 3.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 913 days (2.5 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 119 kg; Height: 161 cm; BMI: 45.9.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A06J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 200 mg.
  Slide TCGA-AX-A06J-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 95; Percent normal cells: 3; Percent necrosis: 1; Percent stromal cells: 8; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-AX-A06J-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 3; Percent necrosis: 20; Percent stromal cells: 2; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A06J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form: Pregnancies full term count: 3; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Carboplatin & Paclitaxel.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 913 days; disease-specific survival: no event (censored), 913 days; disease-free interval: no event (censored), 913 days; progression-free interval: no event (censored), 913 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A06J-01A-11D-A00X-01): tumor purity 0.72, ploidy 2.05, whole-genome doublings 0.
